Somatic mutation profile of tumor specimen MP2PRT-PARHUN-TMP1-A (aliquot MP2PRT-PARHUN-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARHUN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,806 days).
Specimen MP2PRT-PARHUN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a9072bb-e9e4-4597-8bb8-2711cc3474c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHUN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHUN-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc0e6d24-a78b-4b9c-9e12-d8cd0e9385b8

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 4, Frame Shift Del 2, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FA2H | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs139261750; called by muse, mutect2, varscan2
- MUC12 | c.1025T>A p.I342N (on ENST00000379442; = p.I199N on NM_001164462.1) | Missense Mutation (SNP) | VAF 322/633 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.263); catalogued as rs371891242; called by muse, mutect2
- CEP295NL | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 227/515 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CSNKA2IP | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MUC4 | c.10670_10672del p.D3557del | In Frame Del (DEL) | VAF 80/268 reads (30%) | called by pindel, varscan2
- OR4N2 | c.493del p.R165Afs*34 | Frame Shift Del (DEL) | VAF 234/1183 reads (20%) | called by mutect2, pindel, varscan2
- ZNRF1 | c.166_175del p.G56Wfs*104 | Frame Shift Del (DEL) | VAF 169/667 reads (25%) | called by pindel, varscan2*
- AC092835.1 | c.771C>T p.A257= | Silent (SNP) | VAF 155/363 reads (43%) | called by muse, mutect2, varscan2
- IGHV4-61 | c.355_356insGGAG p.*119delinsGR | Silent (INS) | VAF 36/88 reads (41%) | called by pindel, varscan2
- IGKV2D-24 | c.360T>C p.P120= | Silent (SNP) | VAF 102/130 reads (78%) | called by muse, mutect2
- OTOG | c.8595C>T p.C2865= | Silent (SNP) | VAF 157/332 reads (47%) | catalogued as rs1234069771, COSV68036107; called by muse, mutect2, varscan2
- PCDHGA4 | c.636C>T p.D212= | Silent (SNP) | VAF 129/431 reads (30%) | catalogued as rs750434737, COSV53977600; called by muse, mutect2, varscan2
- PZP | c.234G>A p.A78= | Silent (SNP) | VAF 129/303 reads (43%) | catalogued as rs368446783, COSV54353837; called by muse, mutect2, varscan2
- TRIM67 | c.777G>A p.P259= | Silent (SNP) | VAF 134/428 reads (31%) | catalogued as rs1440968656; called by muse, varscan2
- TTN | c.13407A>T p.T4469= (on ENST00000591111; = p.T4423= on NM_003319.4) | Silent (SNP) | VAF 123/276 reads (45%) | called by muse, mutect2, varscan2
- ABCA12 | c.164-11358C>G | Intron (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- VSTM2A | c.*89G>T | 3'UTR (SNP) | VAF 169/385 reads (44%) | catalogued as COSV101281075; called by muse, mutect2, varscan2
